Gene-level copy-number profile of tumor specimen TCGA-LN-A5U5-01A from TCGA case TCGA-LN-A5U5, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IV; Tumor grade: G2; Age at diagnosis: 57.5 years (20,993 days).
Specimen TCGA-LN-A5U5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.1ae5f13b-2a11-4ffd-8903-969284a541db.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-LN-A5U5-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2.
https://portal.gdc.cancer.gov/files/96c4b4d5-8859-4aab-8545-2854e2e26431

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 63; copy number 1: 10,171; copy number 2: 36,869; copy number 3: 10,003; copy number 4: 1,717; copy number 5: 231; copy number 6: 764.

Homozygous deletions (total copy number 0; autosomes only): 63 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:140,898,423–140,992,659, 2 genes: LRRC57P1, Y_RNA.
- chr9:20,341,669–20,622,499, 1 gene (within-gene range 0–2): MLLT3.
- chr9:20,502,265–22,128,103, 59 genes (within-gene range 0–2): MIR4474, AL163193.1, FOCAD, FOCAD-AS1, MIR491, SNORA30B, HACD4, IFNNP1, IFNB1, IFNWP4, AL390882.1, IFNW1, Y_RNA, IFNA21, IFNWP15, IFNA4, IFNWP9, IFNA7, IFNA10, IFNWP18, IFNA16, IFNA17, IFNWP5, IFNA14, IFNA22P, IFNA5, IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1.
- chr10:34,488,583–34,488,878, 1 gene: ELOBP4.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 995 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:149,229,356–198,222,513, 880 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr11:30,584,130–36,697,867, 115 genes, copy number 6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 7,784. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
